Gene-level copy-number profile of tumor specimen TCGA-BB-7866-01A from TCGA case TCGA-BB-7866, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: GX; Age at diagnosis: 40.5 years (14,810 days).
Specimen TCGA-BB-7866-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.d4c22e16-81ec-4e2d-a0d0-af61229a8864.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-BB-7866-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 806 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/f27d2840-282f-4a1c-b7d0-cf4158aa6891

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 8,708; copy number 2: 50,723; copy number 3: 70; copy number 6: 221; copy number 8: 20; copy number 10: 75.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-BB-7866-01): tumor purity 0.76, ploidy 1.93, whole-genome doublings 0 (call status: maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 316 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:127,946,559–127,960,695, 2 genes, copy number 6: TMEM75, MIR1205.
- chr20:21,085,576–21,755,350, 26 genes, copy number 6: LINC00237, AL121759.2, RPL24P2, KIZ, RNA5SP477, AL121759.1, KIZ-AS1, RPS15AP1, ZNF877P, AL117332.1, XRN2, NKX2-4, AL158013.1, RN7SKP140, AL133325.1, AL133325.3, GSTM3P1, NKX2-2, NKX2-2-AS1, AL133325.2, LINC01727, LINC01726, AL121590.1, PAX1, SLC25A6P1, RPL41P1.
- chr20:22,220,554–34,927,962, 288 genes, copy number 6–10 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 6,321. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
